Somatic mutation profile of tumor specimen 0DPMS3 from CCDI case PBCDUA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.2 years (4,098 days).
Specimen 0DPMS3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36058a76-0000-4058-a6b7-572b46cf4188.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPMQS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10845b81-41f0-4c5d-b02c-c9d96d15264a

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Nonsense Mutation 1, Splice Site 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 142/731 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FBXO28 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 68/351 reads (19%) | catalogued as COSV64800331; called by muse, mutect2, varscan2
- KIAA0825 | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 53/570 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565529285, COSV56950874; called by muse, mutect2
- PDZRN4 | c.1723G>A p.E575K (on ENST00000402685 / NM_001164595.2; = p.E317K on NM_013377.4) | Missense Mutation (SNP) | VAF 101/294 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs762428366; called by muse, mutect2, varscan2
- ABCC11 | c.3258+1G>A p.X1086_splice | Splice Site (SNP) | VAF 16/157 reads (10%) | called by muse, mutect2, varscan2
- CELSR1 | c.7084C>T p.L2362F | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CTNNA1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 85/315 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- FAM161B | c.1429C>A p.P477T (on ENST00000651776; = p.P414T on NM_152445.3) | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- ZNF80 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 37/283 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF823 | c.153C>T p.N51= (on ENST00000341191 / NM_001297610.2; = p.N7= on NM_017507.2) | Silent (SNP) | VAF 24/318 reads (8%) | catalogued as COSV57872651; called by muse, mutect2
- COPRS | c.99+222del | Intron (DEL) | VAF 3/25 reads (12%) | called by pindel, varscan2
